Somatic mutation profile of tumor specimen TCGA-F9-A4JJ-01A (aliquot TCGA-F9-A4JJ-01A-11D-A25F-10) from TCGA case TCGA-F9-A4JJ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 35.3 years (12,893 days).
Specimen TCGA-F9-A4JJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7128eb7-e863-4f8a-8264-d3adbed1353e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F9-A4JJ-10A (Blood Derived Normal), aliquot TCGA-F9-A4JJ-10A-01D-A25F-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71ed988d-f66a-4d67-a758-bd91e20d5313

The open-access MAF lists 41 somatic variants for this specimen: 32 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 7, 5'Flank 2, In Frame Del 1, Splice Site 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2A1 | c.2464dup p.R822Pfs*39 | Frame Shift Ins (INS) | VAF 24/85 reads (28%) | catalogued as rs751365374; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ACAD8 | c.794G>A p.G265D | Missense Mutation (SNP) | VAF 66/151 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55540124; called by muse, mutect2, varscan2
- ASXL3 | c.182A>G p.N61S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.048); catalogued as COSV52464215; called by muse, mutect2, varscan2
- ATXN7 | c.1861C>T p.H621Y | Missense Mutation (SNP) | VAF 99/344 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs772718664, COSV55750178; called by muse, mutect2, varscan2
- CDH8 | c.1958T>G p.I653S | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.105); catalogued as COSV54863058; called by muse, mutect2, varscan2
- CGN | c.2150G>A p.R717Q | Missense Mutation (SNP) | VAF 93/186 reads (50%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.892); catalogued as rs767053366, COSV54969622; called by muse, mutect2, varscan2
- CILP2 | c.1501G>A p.G501S | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.251); catalogued as COSV52274421; called by muse, mutect2, varscan2
- CPS1 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1414655377, COSV51821975; called by muse, mutect2
- EYA4 | c.1915G>T p.A639S (on ENST00000531901 / NM_001301013.1; = p.A633S on NM_004100.5) | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62050680; called by muse, mutect2
- FH | c.1391-2A>C p.X464_splice | Splice Site (SNP) | VAF 29/109 reads (27%) | catalogued as COSV100844971; called by muse, mutect2, varscan2
- FREM2 | c.7736A>G p.K2579R | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV54835726; called by muse, mutect2
- GRIPAP1 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 17/240 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV64551805; called by muse, mutect2
- ITGA3 | c.710A>G p.Y237C | Missense Mutation (SNP) | VAF 88/218 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.379); catalogued as rs1346923588, COSV50309890; called by muse, mutect2, varscan2
- KIF13B | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 136/339 reads (40%) | catalogued as rs757547963, COSV73054378; called by muse, mutect2, varscan2
- LAMP2 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV52352632; called by muse, mutect2
- LRRTM4 | c.357C>A p.N119K | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69139851; called by muse, mutect2, varscan2
- MAP3K19 | c.3620G>C p.C1207S | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1442944882, COSV59638281; called by muse, mutect2, varscan2
- OR8G5 | c.896T>C p.V299A | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as COSV100422195; called by muse, mutect2
- PCDH11X | c.2386C>A p.P796T | Missense Mutation (SNP) | VAF 196/461 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as COSV53460250; called by muse, mutect2, varscan2
- PHF20L1 | c.1491T>G p.C497W | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.283); catalogued as COSV55191734; called by muse, mutect2, varscan2
- PRC1 | c.1403C>A p.P468H | Missense Mutation (SNP) | VAF 20/241 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); catalogued as COSV62695062, COSV62696276; called by muse, mutect2
- PROX1 | c.269C>A p.A90E | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV54778380; called by muse, mutect2
- RBM11 | c.535G>T p.D179Y | Missense Mutation (SNP) | VAF 126/292 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as COSV68748069; called by muse, mutect2, varscan2
- RPL13 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV51949986; called by muse, mutect2, varscan2
- SHE | c.602T>C p.L201S | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV59071554; called by muse, mutect2, varscan2
- SPATA31D1 | c.2656G>A p.V886I | Missense Mutation (SNP) | VAF 91/192 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs777325996, COSV100783042, COSV61195053; called by muse, mutect2, varscan2
- TNXB | c.6296G>A p.R2099H (on ENST00000647633; = p.R1852H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs775167267, COSV64478041; called by muse, mutect2
- TRIO | c.8008G>C p.V2670L | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as COSV59989882; called by muse, mutect2, varscan2
- VPS50 | c.1405T>G p.W469G | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV58507091; called by muse, mutect2, varscan2
- ZNF709 | c.1739G>A p.R580K | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.228); catalogued as COSV67194624; called by muse, mutect2, varscan2
- ATP1B1 | c.331_339del p.K111_K113del | In Frame Del (DEL) | VAF 45/134 reads (34%) | called by mutect2, pindel, varscan2
- IGKV2D-30 | c.233A>G p.N78S | Missense Mutation (SNP) | VAF 21/510 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2
- DCUN1D3 | c.873C>T p.L291= | Silent (SNP) | VAF 83/191 reads (43%) | catalogued as COSV60953140; called by muse, mutect2, varscan2
- DIRAS2 | c.573G>A p.K191= | Silent (SNP) | VAF 110/272 reads (40%) | catalogued as rs201919906, COSV101005812; called by muse, mutect2, varscan2
- ELOA2 | c.1443C>T p.D481= | Silent (SNP) | VAF 54/135 reads (40%) | catalogued as COSV55297873; called by muse, mutect2, varscan2
- FPR3 | c.624T>A p.I208= | Silent (SNP) | VAF 62/143 reads (43%) | catalogued as COSV59329269; called by muse, mutect2, varscan2
- KIAA1755 | c.339G>A p.E113= | Silent (SNP) | VAF 37/171 reads (22%) | catalogued as COSV54074735, COSV54075905; called by muse, mutect2, varscan2
- SPAG7 | c.69T>G p.T23= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV52777112; called by muse, mutect2, varscan2
- TRPM5 | c.2679G>A p.A893= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as rs767855754, COSV50144638, COSV50172403; called by muse, mutect2, varscan2
- AL645933.1 | chr6:31463861 C>T | 5'Flank (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- Y_RNA | chr7:75516195 G>A | 5'Flank (SNP) | VAF 203/550 reads (37%) | called by muse, mutect2, varscan2
